Surgical pathology report (de-identified scan), TCGA case TCGA-XE-AANK, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-XE-AANK-01A (Primary Tumor).

[page 1 of 3]
Ord #=

RESULTED

Collect D/T=

SURGICAL PATHOL

Modifiers:

(1 of 1)

Surgical Pathology Report

Specimen(s) Received
Left testes

Clinical History
Left testicular mass

ICD-O-3
Mixed germ cell tumor
9085/3
Site @ Testis NOS
C62.9
JWB/3/1/14

Gross Description

Left testes: Received fresh from the operating room with the patient's name and medical record number and consists of a testicle and attached spermatic cord measuring 14.4 x 3.9 x 3.5 cm. in greatest dimension. The spermatic cord measures 9.5 cm. in length and 1.7 cm. in diameter. The testicle measures 4.7 x 4.4 x 3.5 cm. Upon bivalving the testis there is a well-circumscribed with irregular border pale tan and dark tan mass measuring 3.1 x 3.1 x 3.0 cm. The mass does not grossly involve the epididymis or tunica albuginea or tunica vaginalis. The tumor abuts the tunica albuginea at its closest point but does not grossly invade. The tumor does grossly involve the epididymis and approaches it by 0.5 cm. at its closest point. No other gross lesions or nodules are identified. Representative sections are submitted as follows:

- 1 proximal spermatic cord
- 2 mid spermatic cord
- 3 distal spermatic cord
- 4 representative section of nodule and adjacent parenchyma
- 5 representative of tumor at closest point to tunica albuginea and vaginalis
- 6 uninvolved parenchyma
- 7 Representative section of tumor at its closest point to epididymis
- 8-12 additional representatives of tumor
- 13-18 additional representative sections of tumor

Date of Dictation:

Gross Description By:

[page 2 of 3]
(Continued)

Acct#:

Microscopic Description
Performed.

Final Pathologic Diagnosis

Specimen Type: Radical Orchiectomy

Laterality: Left

Focality: Unifocal

Tumor Size: 3.1 cm.

Histologic Type: Mixed germ cell tumor: embryonal carcinoma (60%), yolk sac tumor (20%), seminoma (10%), and mature teratoma (10%).

Intratubular germ cell neoplasia is present.

Tumor is limited to the testis. Tumor does not involve rete testis, epididymis, peri-hilar fat, spermatic cord, tunica vaginalis or scrotal wall.

Lymphovascular Invasion: Present (slide 12).

Margin: Spermatic cord margin is negative.

Remaining testicular tissue shows atrophy.

Pathologic Tumor Stage: pT2NXMX S1 (Stage IS)

Comment: Immunostains show the embryonal carcinoma positive for Pankertin, CD30, and PLAP and negative for Alpha-feto Protein.

Attending Pathologist:

***Electronically Signed Out By

*** Note: Immunohistochemistry testing was developed and its performance characteristics determined by

It has not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigation or research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA-88) as qualified to perform high complexity clinical laboratory testing. ***

Per TSS dx discrepancy
from TCGA tumor is:
Seminoma 20%
Embryonal 50%
Yolk Sac 20%
M. Teratoma 10%

Criteria	Yes?	No?

[page 3 of 3]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Embryonal Carcinoma 60%, Yolk Sac Tumor 20%, Seminoma 10%, Mature Teratoma 10%	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Seminoma 20%, Embryonal Carcinoma 50%, Yolk Sac Tumor 20%, Teratoma (Mature) 10%	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	histologic heterogeneity characteristic of mixed germ cell tumors	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director	_____	Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file 419da93c-b4a2-40d8-946e-9d40151b760c (TCGA-XE-AANK-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).